Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A6E9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A6E9-06A (Metastatic).

ICD-O-3

Melanoma, malignant NOS
8720/3
Site: Inguinal lymph node
C77.4
9/26/25/13

Department of Cancer Pathology

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Melanoma of the left lower leg. Metastases to the left inguinal lymph nodes**

Date of admission:

Material:

1) Material: inguinal lymph nodes. Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Metastases of malignant melanoma in lymph nodes NO IA/I. (8720/6 T-08810)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Surgical specimen sized: 14 x 9 x 3 cm. Skin specimen sized: 11 x 2.5 cm.
Lymph nodes of 0.7 to 3.5 cm in diameter in the cross-section.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Case is (check one): Reviewed by this pathologist	QUALIFIED	DISQUALIFIED
Reviewed by this pathologist	5/20/13	

Source: NCI Genomic Data Commons file 35e54d93-b2b3-4c35-a736-d275bdbe606e (TCGA-D9-A6E9.C715D5BB-268B-4F22-8BA3-85E8F65A383B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).